Surgical pathology report (de-identified scan), TCGA case TCGA-XJ-A83H, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-XJ-A83H-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

NAME: SURG PATH #:
MR #: SPECIMEN CLASS:
BILLING #: ALT ID #:
LOCATION: DATE OF PROCEDURE:
AGE: SEX: M DATE RECEIVED:
DOB: TIME RECEIVED:
PHYSICIAN: DATE OF REPORT:
COPY TO: DATE OF PRINTING:

Material Received:

A: Bladder neck (margin)
B: Prostate

History:

year old male with a clinical history of prostate cancer.

Final Diagnosis:

- A. Bladder neck (margin):
There is no evidence of malignancy.
- B. Prostate, prostatectomy:
Adenocarcinoma, moderately differentiated, Gleason score 3+4=7 (see comment).

Comment:

Prostate
Procedure: Prostatectomy
Histologic Type: Adenocarcinoma
Histologic Grade: Moderately well differentiated.
Gleason Pattern
Primary Pattern: 3
Secondary Pattern: 4
Total Gleason Score (Primary + Secondary): 4+3
Proportion (percent) of prostate involved by tumor: 10
Tumor Multicentricity: Yes, both lobes
Extraprostatic Extension: No
Seminal Vesicle Invasion: Not involved
Margins: Margins are clear
Perineural Invasion : No
Vascular Invasion : No
Additional Pathologic Findings:
Lymph Nodes: N/A
Gross Picture Taken: N/A
Pathologic Staging: pT2cNXMX

Primary Tumor (pT)
Not identified
pT2: Organ confined

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/5/16/14

MR #:

Page 1 of 2

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

pT2a: Unilateral, involving one-half of 1 side ("lobe") or less
pT2b: Unilateral, involving more than one-half of 1 side ("lobe") but not both sides ("lobes")
pT2c: Bilateral disease

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By
MD, Attending Physician
M.D. Fellow

Interpreted by:

Gross Description:

A. Received fresh labeled "posterior bladder neck". The specimen is submitted in cassette A1FS.

B. Received in formalin labeled "prostate" is a prostate weighing 33grams and measuring 5 cm from superior to inferior margin, 5.5cm from left to right margin and 3.3cm from anterior to posterior margin. The left side of prostate is inked in blue and the right side inked black. The specimen is bisected to separate the anterior and the posterior portion and each portion is serially sectioned from apex to the base to reveal a tan cut surface. The specimen is submitted as follow:

Cassette B1:	Right bladder neck margin (serially sectioned)
Cassette B2:	Left bladder neck margin (serially sectioned)
Cassette B3:	Right distal urethral margin (serially sectioned)
Cassette B4:	Left distal urethral margin (serially sectioned)
Cassette B5:	Right seminal vesicle margin
Cassette B6:	Left seminal vesicle margin
Cassette B7:	Representative section from right middle anterior prostate
Cassette B8:	Representative section from left middle anterior prostate
Cassette B9 through B16:	Entire posterior right lobe from apex to base
Cassette B17 through B24:	Entire posterior left lobe from apex to base

Intraoperative Consultation:

A1FS: Prostate, "bladder neck margin":
No evidence of malignancy.
MD, Attending Physician

MR #:

Page 2 of 2

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 887b3375-027c-4248-9fb2-9a407a79a9a6 (TCGA-XJ-A83H.B4E981CF-B54B-422D-9FD4-E867FAB1FAA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).